Somatic mutation profile of tumor specimen 0DESTZ from CCDI case PBBRDL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Soft palate, NOS; Age at diagnosis: 15.8 years (5,762 days).
Specimen 0DESTZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cb5c017-d498-4ddd-abee-f2994f745152.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DESU0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8366dd37-70c4-4b9d-8f2c-7761f64959cc

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1H1 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 68/580 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.265); catalogued as rs777505460; called by muse, varscan2
- HAPLN4 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs914506060; called by muse, varscan2
- MAGEC3 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1030898483; called by muse, varscan2
- NBEA | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 94/803 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1190989650, COSV59763269; called by muse, varscan2
- OR4S1 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 70/576 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1319109423; called by muse, varscan2
- PWWP2B | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768043921; called by muse, varscan2
- CKAP2L | c.1547A>C p.E516A | Missense Mutation (SNP) | VAF 143/952 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.112); called by muse, varscan2
- KCNN2 | c.705C>G p.F235L (on ENST00000264773; = p.F447L on NM_021614.4) | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, varscan2
- MMP1 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 671/1205 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, varscan2
- PTPN1 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 82/634 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SGO2 | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 96/663 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM69 | c.244A>T p.R82* | Nonsense Mutation (SNP) | VAF 63/581 reads (11%) | called by muse, varscan2
- WWOX | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 81/798 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DCC | c.276T>A p.L92= | Silent (SNP) | VAF 102/641 reads (16%) | called by muse, varscan2
- GOLGB1 | c.9177G>T p.L3059= | Silent (SNP) | VAF 130/513 reads (25%) | called by muse, varscan2
- KANK4 | c.909C>A p.I303= | Silent (SNP) | VAF 37/182 reads (20%) | catalogued as rs770579598, COSV100587091; called by muse, varscan2
- MFHAS1 | c.1002G>A p.L334= | Silent (SNP) | VAF 44/362 reads (12%) | called by muse, varscan2
- SIRT1 | c.1794G>A p.P598= | Silent (SNP) | VAF 132/767 reads (17%) | catalogued as rs143664372; called by muse, varscan2
- ZNF395 | c.483C>T p.D161= | Silent (SNP) | VAF 36/271 reads (13%) | catalogued as rs752754037, COSV100733873; called by muse, varscan2
- BLM | c.4077-78C>A | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, varscan2
- GP6 | c.*376C>A | 3'UTR (SNP) | VAF 37/254 reads (15%) | catalogued as COSV100117659; called by muse, varscan2
- SLCO1A2 | c.1272-33T>C | Intron (SNP) | VAF 41/215 reads (19%) | called by muse, varscan2
